Somatic mutation profile of tumor specimen MMRF_2000_1_BM_CD138pos (aliquot MMRF_2000_1_BM_CD138pos_T1_KBS5U_L07279) from MMRF case MMRF_2000, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.4 years (18,060 days).
Specimen MMRF_2000_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ae661a-b7db-42ec-9844-8e84676781e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2000_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2000_1_PB_Whole_C3_KBS5U_L07280; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/615e3e1d-dd37-4fe6-ae7e-9ced184c0191

The open-access MAF lists 46 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 12, Silent 6, Intron 4, 5'UTR 3, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR1 | c.22-6C>T | Splice Region (SNP) | VAF 123/253 reads (49%) | catalogued as rs1440532248; called by muse, mutect2, varscan2
- C5AR1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs200059632, COSV61893086; called by muse, mutect2, varscan2
- CCND1 | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57122487; called by muse, mutect2, varscan2
- DMD | c.2451G>T p.Q817H | Missense Mutation (SNP) | VAF 67/69 reads (97%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs1468177610; called by muse, mutect2, varscan2
- IGHV2-70 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs775504623; called by muse, mutect2
- IGHV3-33 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs371479041; called by muse, mutect2
- MTFR2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs570529220; called by muse, mutect2, varscan2
- NEGR1 | c.175A>G p.R59G | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV63250955; called by muse, mutect2, varscan2
- NRG1 | c.1850G>A p.R617H (on ENST00000405005 / NM_013964.5; = p.R622H on NM_013956.5) | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs772708330; called by muse, mutect2, varscan2
- RXFP3 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419117408; called by muse, mutect2, varscan2
- SLC30A10 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV63070405, COSV63074070; called by muse, mutect2, varscan2
- UPRT | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 213/282 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV64912097; called by muse, mutect2, varscan2
- CENPM | c.137+2dup | Splice Region (INS) | VAF 43/98 reads (44%) | called by mutect2, pindel, varscan2
- CORO2A | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP1C | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- IGKJ2 | c.1_11del p.C2Pfs*? | Frame Shift Del (DEL) | VAF 126/136 reads (93%) | called by mutect2, pindel, varscan2
- IGKV1-33 | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- LGALS3 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXTR | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PNLIPRP2 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR3 | c.2265C>G p.F755L | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB11 | c.891G>A p.A297= | Silent (SNP) | VAF 78/151 reads (52%) | catalogued as rs756322049; called by muse, mutect2, varscan2
- EPPK1 | c.87G>A p.T29= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as rs782769363, COSV101599770; called by muse, mutect2, varscan2
- FSCN1 | c.1236C>T p.D412= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs144028572; called by muse, mutect2, varscan2
- GFRAL | c.537T>G p.P179= | Silent (SNP) | VAF 109/243 reads (45%) | called by muse, mutect2, varscan2
- NSMAF | c.2176A>C p.R726= | Silent (SNP) | VAF 88/208 reads (42%) | called by muse, mutect2, varscan2
- VPS13B | c.2253A>T p.G751= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- ABI2 | c.*11094A>C | 3'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- AUTS2 | c.1903-37A>G | Intron (SNP) | VAF 75/143 reads (52%) | called by muse, mutect2, varscan2
- CCDC85A | c.*236A>G | 3'UTR (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- CCND1 | c.-153G>A | 5'UTR (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- COL11A2 | c.-18C>T | 5'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- EFR3B | c.-28C>T | 5'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- ENOPH1 | c.*63T>C | 3'UTR (SNP) | VAF 107/196 reads (55%) | called by muse, mutect2, varscan2
- FAM149B1 | c.*1696T>G | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- IL13RA1 | c.828+21T>G | Intron (SNP) | VAF 23/28 reads (82%) | called by muse, mutect2, varscan2
- KIAA0319 | c.*1738C>T | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*1536C>T | 3'UTR (SNP) | VAF 35/65 reads (54%) | catalogued as rs1441275015; called by muse, mutect2, varscan2
- MCMBP | c.*63T>C | 3'UTR (SNP) | VAF 36/84 reads (43%) | catalogued as rs947142140; called by muse, mutect2, varscan2
- MDH2 | c.885+99C>T | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- MOB4 | c.*2742T>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2
- MRPS14 | c.*1034T>G | 3'UTR (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- NOTCH2 | c.751+579A>C | Intron (SNP) | VAF 20/146 reads (14%) | called by mutect2, varscan2
- NPTXR | c.*73A>C | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- SNIP1 | c.*427G>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- SPHKAP | c.*1000G>A | 3'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as rs1371150399; called by muse, mutect2, varscan2
